Gene-level copy-number profile of tumor specimen TCGA-57-1583-01A from TCGA case TCGA-57-1583, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.0 years (21,167 days).
Specimen TCGA-57-1583-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f9fc5722-4216-43f8-b7bb-95752acc78f6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-57-1583-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cbb07757-fdd4-4b4f-8597-b25944815ef5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,952; copy number 2: 14,481; copy number 3: 21,969; copy number 4: 18,473; copy number 5: 606; copy number 6: 425; copy number 7: 526; copy number 8: 221; copy number 9: 456; copy number 10: 15; copy number 11: 90; copy number 12: 299; copy number 13: 175; copy number 14: 83; copy number 16: 9; copy number 18: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-57-1583-01): tumor purity 0.92, ploidy 3.22, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,865 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,650,149–44,355,260, 34 genes, copy number 7 (within-gene range 3–7): KDM4A, AL451062.2, KDM4A-AS1, ST3GAL3, ST3GAL3-AS1, U6, AL451062.1, MIR6079, SHMT1P1, ARTN, AL357079.1, AL357079.3, IPO13, AL357079.2, DPH2, ATP6V0B, B4GALT2, CCDC24, SLC6A9, AL139220.2, AL139220.1, KRT8P47, RN7SL479P, KLF17, AL356653.1, KLF18, AL359839.1, Y_RNA, OOSP1P1, AL035417.1, AL035417.2, DMAP1, ERI3, ERI3-IT1.
- chr1:44,850,522–45,011,324, 6 genes, copy number 12 (within-gene range 3–12): EIF2B3, RNA5SP47, CCNB1IP1P1, PPIAP35, MRPS17P1, HECTD3.
- chr1:81,080,790–81,992,436, 14 genes, copy number 12 (within-gene range 3–12): MTND2P30, RPL7P10, AL357632.1, AC093154.1, RN7SKP247, ADGRL2, HNRNPA3P14, ARID3BP1, AL138799.1, AL138799.3, MED28P8, AC117944.1, AL138799.2, ST13P20.
- chr2:32,557,273–35,185,689, 29 genes, copy number 7–8 (within-gene range 4–8): BIRC6-AS2, AL133243.4, TTC27, MIR4765, LINC00486, LINC00486, Y_RNA, LTBP1, H2ACP2, AC019127.1, RNA5SP91, RNA5SP92, MIR4430, RASGRP3, RASGRP3-AS1, FAM98A, AC017050.1, ATP6V0E1P3, HNRNPA1P61, LINC01320, MYADML, SLC25A5P2, LINC01318, AC008170.1, AC073218.1, AC012593.2, AC012593.1, RN7SL602P, AC019064.1.
- chr2:43,620,878–52,630,078, 140 genes, copy number 8–12 (broad region; genes not listed).
- chr4:64,275,257–67,701,155, 39 genes, copy number 7–12: TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1, AC104689.2, LINC02232, AC107058.1, EFL1P2, AC096754.1, LINC02835, EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3, RNU6-699P, AC104806.2, RNU1-63P, RNA5SP527, AC104806.1, CENPC, STAP1, AC096720.2, UBA6, AC096720.1.
- chr4:67,716,375–67,884,002, 7 genes, copy number 7: ST3GAL1P1, AC079880.1, AC079880.2, GNRHR, SNORA62, TMPRSS11CP, TMPRSS11D.
- chr4:86,336,318–86,336,614, 1 gene, copy number 8: RN7SKP96.
- chr4:162,984,795–162,985,416, 1 gene, copy number 7: AC084752.1.
- chr4:168,828,919–170,283,723, 26 genes, copy number 7–9: AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612.
- chr5:130,655,383–133,026,604, 66 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr7:3,264,032–3,302,452, 1 gene, copy number 7: SDK1-AS1.
- chr7:3,337,889–3,338,601, 1 gene, copy number 7: AC092427.1.
- chr7:13,854,355–14,986,074, 9 genes, copy number 16: AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1, GTF3AP5.
- chr7:20,582,072–21,028,813, 9 genes, copy number 7: EEF1A1P27, AC002486.2, ABCB5, AC002486.1, SP8, RPL23P8, LINC01162, RPS26P30, AC080068.1.
- chr7:28,279,211–30,504,841, 45 genes, copy number 7–9: PPIAP80, CREB5, AC005105.1, TRIL, AC005013.1, AC005162.2, AC005162.1, CPVL, CPVL-AS1, AC005232.1, AC004593.2, CHN2, AC004593.1, CHN2-AS1, NANOGP4, AC007255.1, GTF3C6P3, PRR15, ZNRF2P2, TMSB4XP3, DPY19L2P3, MIR550A3, WIPF3, AC004912.1, SCRN1, FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1, AC006978.2, AC006978.1, LINC01176, NOD1, AC006027.1, GGCT.
- chr7:128,297,685–131,948,953, 130 genes, copy number 9–11 (broad region; genes not listed).
- chr7:142,111,749–142,962,363, 98 genes, copy number 9 (broad region; genes not listed).
- chr7:147,671,711–152,122,340, 136 genes, copy number 12–13 (within-gene range 4–13) (broad region; genes not listed).
- chr8:55,067,585–56,776,874, 35 genes, copy number 9: AC084834.1, XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2.
- chr8:127,686,343–132,675,592, 55 genes, copy number 10–13 (within-gene range 3–13): CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6.
- chr11:75,100,563–75,206,549, 1 gene, copy number 8 (within-gene range 4–8): SLCO2B1.
- chr11:75,206,048–80,528,066, 113 genes, copy number 7–11 (broad region; genes not listed).
- chr18:5,392,381–9,285,985, 68 genes, copy number 8–12 (within-gene range 3–12) (broad region; genes not listed).
- chr18:9,708,275–10,372,387, 14 genes, copy number 8 (within-gene range 4–8): RAB31, AP000902.1, ZNF415P1, RN7SL862P, AC006238.2, RNA5SP449, PIGPP4, TXNDC2, AC006238.1, VAPA, RNA5SP450, AP005271.1, AP005209.2, AP005209.1.
- chr18:30,954,820–33,751,195, 59 genes, copy number 8: AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1, AC091198.1, ASXL3.
- chr18:37,960,220–37,992,413, 1 gene, copy number 9 (within-gene range 1–9): AC108452.1.
- chr18:46,786,699–47,176,364, 17 genes, copy number 7: AC090241.3, PIAS2, AC090241.1, AC090373.1, KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2, AC012254.5, AC012254.1, AC012254.3, HDHD2, AC012254.2, AC012254.4, IER3IP1.
- chr19:13,144,058–17,821,574, 240 genes, copy number 7 (broad region; genes not listed).
- chr19:28,683,071–34,964,229, 152 genes, copy number 7–12 (broad region; genes not listed).
- chr19:38,647,649–39,032,785, 26 genes, copy number 11 (within-gene range 1–11): ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1.
- chr19:39,655,913–40,021,038, 17 genes, copy number 14: LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546.
- chr19:44,228,729–44,305,046, 1 gene, copy number 12 (within-gene range 1–12): ZNF235.
- chr19:44,259,880–44,536,613, 12 genes, copy number 12: ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3.
- chr19:45,485,294–46,610,782, 66 genes, copy number 14 (within-gene range 4–14) (broad region; genes not listed).
- chr19:58,012,589–58,605,223, 64 genes, copy number 8–13 (broad region; genes not listed).
- chr22:29,730,956–31,388,837, 81 genes, copy number 12 (broad region; genes not listed).
- chr22:31,676,256–33,145,861, 49 genes, copy number 7: PRR14L, DEPDC5, Z82190.2, RN7SL20P, AL022331.1, RNU6-201P, Z82190.1, C22orf24, YWHAH, AL008719.1, LINC02558, RN7SL305P, Z74021.1, SLC5A1, AP1B1P1, Z83839.1, AP1B1P2, Z83839.2, C22orf42, AL008723.1, AL008723.3, RFPL2, IGLCOR22-1, SLC5A4-AS1, SLC5A4, CPSF1P1, AL008723.2, AL021937.3, RFPL3, IGLCOR22-2, RFPL3S, AL021937.6, AL021937.5, AL021937.1, IGLVIVOR22-2, AL021937.4, AL021937.2, RTCB, BPIFC, FBXO7, SYN3, SYN3-AS1, RNA5SP497, Z73495.1, TIMP3, Z83846.1, LINC01640, Z82198.1, Z82198.3.
- chr22:33,164,063–33,322,813, 2 genes, copy number 7: Z82198.2, Z82173.1.

Autosomal genes at a single copy (total copy number 1): 1,952. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
